TCGA case TCGA-05-4244 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/34040b83-7e8a-4264-a551-b16621843e28

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 70.5 years (25,752 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 0 days; Sites of involvement: Peripheral Lung.

Follow-up (1 entry)
- Days to follow up: 0 days; Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 38.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-05-4244-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.9; Shortest dimension: 0.3.
  Slide TCGA-05-4244-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 20.
  Slide TCGA-05-4244-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 20.
- Sample TCGA-05-4244-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-05-4244-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Lower; Location lung parenchyma: Peripheral Lung.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 0 days; disease-specific survival: no event (censored), 0 days; progression-free interval: no event (censored), 0 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-05-4244-01A-01D-1877-01): tumor purity 0.44, ploidy 4.24, whole-genome doublings 1.
